Somatic mutation profile of tumor specimen MMRF_1805_1_BM_CD138pos (aliquot MMRF_1805_1_BM_CD138pos_T1_KHS5U_L14858) from MMRF case MMRF_1805, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.6 years (17,741 days).
Specimen MMRF_1805_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccb3802e-9606-49ab-9613-7fa95205c143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1805_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1805_1_PB_WBC_C3_KHS5U_L14859; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/273d39aa-7aaf-427b-9ea0-4ce12b62fde4

The open-access MAF lists 48 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 14, Silent 6, 5'UTR 4, Intron 3, 3'Flank 2, Nonsense Mutation 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAG1 | c.2106C>A p.C702* | Nonsense Mutation (SNP) | VAF 16/207 reads (8%) | catalogued as rs863223680, HM080115; ClinVar: pathogenic; called by muse, mutect2
- CYYR1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54832373, COSV54839783; called by muse, mutect2
- FCMR | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65567188; called by muse, mutect2
- MROH2B | c.4487A>T p.K1496M | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101270987; called by muse, mutect2
- AL096814.1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP290 | c.5306A>G p.Q1769R | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- CSRNP3 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT2 | c.7655T>G p.V2552G | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- GMPS | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- MLH3 | c.936C>A p.C312* | Nonsense Mutation (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- NEK3 | c.905T>G p.L302W | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); called by muse, mutect2
- PPARGC1A | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.857); called by muse, mutect2
- SHC3 | c.609+2T>G p.X203_splice | Splice Site (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- SIGLEC9 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.215); called by muse, mutect2
- SLC17A6 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.477); called by muse, mutect2
- THBD | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- TXNDC16 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- USP44 | c.1655T>G p.V552G | Missense Mutation (SNP) | VAF 16/574 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- LMTK3 | c.3375C>T p.G1125= | Silent (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- MGAM | c.5196A>G p.K1732= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- PIKFYVE | c.4620G>A p.A1540= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs760717016, COSV52244739; called by muse, mutect2, varscan2
- PLXNA3 | c.1608G>A p.L536= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- PXDNL | c.2493G>A p.P831= | Silent (SNP) | VAF 13/359 reads (4%) | catalogued as COSV100681216, COSV62481028; called by muse, mutect2
- ZNF525 | c.1023C>T p.Y341= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- ABI3BP | c.1576+14065A>C | Intron (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- BTK | c.*75A>G | 3'UTR (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- CACNA1D | c.*364G>C | 3'UTR (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- CBX7 | c.*679G>A | 3'UTR (SNP) | VAF 9/176 reads (5%) | catalogued as rs931803163; called by muse, mutect2
- CFHR4 | c.*275T>C | 3'UTR (SNP) | VAF 11/197 reads (6%) | catalogued as rs1166215880; called by muse, mutect2
- CHAC1 | chr15:40953274 T>C | 5'Flank (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- COL5A1 | c.109+7197A>C | Intron (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- FBXO45 | c.*1820A>G | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- FGF12 | c.-241C>T | 5'UTR (SNP) | VAF 14/421 reads (3%) | called by muse, mutect2
- GLIS3 | c.*1932A>C | 3'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*2039C>A | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- KAT7 | c.*703G>A | 3'UTR (SNP) | VAF 17/319 reads (5%) | called by muse, mutect2
- KLHL1 | c.-297C>T | 5'UTR (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- KRTAP20-1 | c.*6T>G | 3'UTR (SNP) | VAF 20/550 reads (4%) | called by muse, mutect2
- LINC02203 | c.-414T>G | 5'UTR (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- MSL2 | c.-577A>G | 5'UTR (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- PFKFB3 | c.*1955C>T | 3'UTR (SNP) | VAF 7/142 reads (5%) | catalogued as rs1012499942; called by muse, mutect2
- PIWIL1 | c.*62T>G | 3'UTR (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- PRR9 | c.*215T>A | 3'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- RIMS3 | chr1:40625646 C>T | 3'Flank (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- SNX18 | chr5:54545257 A>C | 3'Flank (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- SOX11 | c.*3196A>G | 3'UTR (SNP) | VAF 10/243 reads (4%) | called by muse, mutect2
- TMEM132D | c.*1287C>T | 3'UTR (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- XIRP2 | c.38-26124A>G | Intron (SNP) | VAF 9/164 reads (5%) | catalogued as rs890400644; called by muse, mutect2
